Somatic mutation profile of tumor specimen TCGA-LI-A67I-01A (aliquot TCGA-LI-A67I-01A-31D-A307-09) from TCGA case TCGA-LI-A67I, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 75.8 years (27,671 days).
Specimen TCGA-LI-A67I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1b2fa67-d6f7-4d7e-836e-69ba786dc2b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LI-A67I-10A (Blood Derived Normal), aliquot TCGA-LI-A67I-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6c32ed8-7f9f-4b8f-b24e-ff5ef27a5fff

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Frame Shift Del 4, Nonsense Mutation 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.200T>A p.I67K | Missense Mutation (SNP) | VAF 100/128 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as CM981666, COSV64291076, COSV64292219, COSV64299142; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 92/147 reads (63%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC3 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 95/160 reads (59%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as rs759534433, COSV53319352; called by muse, mutect2, varscan2
- AHNAK | c.7739C>T p.S2580F | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99947507; called by muse, mutect2
- AK9 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV53424247; called by muse, mutect2, varscan2
- ARHGEF7 | c.2582A>G p.N861S (on ENST00000646102 / NM_001354046.1; = p.N645S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as rs1365764374, COSV99521544; called by muse, mutect2, varscan2
- ASAP3 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100369443; called by muse, mutect2
- BCL11A | c.1520G>A p.R507H (on ENST00000335712 / NM_001365609.1; = p.R541H on NM_018014.4) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.231); catalogued as COSV100185687; called by muse, mutect2, varscan2
- CDKN2D | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100224816; called by muse, mutect2, varscan2
- CFAP45 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764409056, COSV63649903; called by muse, mutect2, varscan2
- CRIP3 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV99240350; called by muse, mutect2, varscan2
- DOCK1 | c.4993G>T p.D1665Y | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54734470; called by muse, mutect2, varscan2
- GCM1 | c.1283T>C p.M428T | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99452367; called by muse, mutect2, varscan2
- GLIS1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375119770; called by muse, mutect2, varscan2
- GSPT2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.057); catalogued as rs782057159, COSV100468171; called by muse, mutect2, varscan2
- IDO1 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.322); catalogued as COSV53715909, COSV99503346; called by muse, mutect2, varscan2
- ITGA1 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50892148; called by muse, mutect2, varscan2
- KIF19 | c.1405T>A p.S469T | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV100739068; called by muse, mutect2
- MAML3 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs775691883, COSV72210227; called by muse, mutect2, varscan2
- MSLNL | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs182148221, COSV99036501; called by muse, varscan2
- MUC16 | c.10570G>A p.E3524K | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as rs1230536680, COSV67462076; called by muse, mutect2, varscan2
- PCDH12 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99188389; called by muse, mutect2, varscan2
- PCDHGA11 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.069); catalogued as rs753196648, COSV53936191; called by muse, mutect2, varscan2
- PLCD3 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs759675322, CM161950, COSV59561658; called by muse, mutect2, varscan2
- PPP1R21 | c.2039C>T p.S680F (on ENST00000294952 / NM_001135629.3; = p.S669F on NM_152994.5) | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99682076; called by muse, mutect2
- PPP1R21 | c.2041C>T p.Q681* (on ENST00000294952 / NM_001135629.3; = p.Q670* on NM_152994.5) | Nonsense Mutation (SNP) | VAF 58/202 reads (29%) | catalogued as rs1004264740, COSV54290382, COSV99682081; called by muse, mutect2
- PRRC2A | c.3115C>T p.R1039W | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774017678, COSV65687356; called by muse, mutect2, varscan2
- PSMC3IP | c.632A>C p.N211T (on ENST00000393795 / NM_016556.4; = p.N199T on NM_013290.6) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99518946; called by muse, mutect2, varscan2
- SCN5A | c.5581G>T p.V1861F (on ENST00000333535 / NM_198056.3; = p.V1860F on NM_000335.5) | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs199473636, CM100759, COSV100348398; called by muse, mutect2, varscan2
- SOX17 | c.1219T>C p.Y407H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99810577; called by muse, mutect2, varscan2
- SYK | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as rs769228620, COSV101002460, COSV65324968; called by muse, mutect2, varscan2
- TEKT4 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 154/205 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99726389; called by muse, mutect2, varscan2
- TM4SF1 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100543002; called by mutect2, varscan2
- VPS51 | c.1834G>A p.V612I | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1268381440, COSV54206969; called by muse, mutect2, varscan2
- XKR7 | c.1007G>T p.W336L | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101629260; called by muse, mutect2, varscan2
- ZNF519 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV101645573; called by muse, mutect2, varscan2
- ZNF547 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99987944; called by muse, mutect2, varscan2
- AP1AR | c.770_783del p.G257Efs*2 | Frame Shift Del (DEL) | VAF 99/145 reads (68%) | called by mutect2, pindel, varscan2
- FBN1 | c.8526_8557del p.N2843Pfs*4 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | called by mutect2, pindel, varscan2
- RB1 | c.2400del p.G801Efs*9 | Frame Shift Del (DEL) | VAF 38/67 reads (57%) | called by mutect2, pindel, varscan2
- AC104452.1 | c.894C>T p.R298= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs976237396, COSV56470260; called by muse, mutect2, varscan2
- ALDH5A1 | c.384C>T p.Y128= | Silent (SNP) | VAF 102/174 reads (59%) | catalogued as CM033317, COSV100708807; called by muse, mutect2, varscan2
- CCDC151 | c.726C>T p.L242= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV100710531; called by muse, mutect2, varscan2
- DCHS1 | c.9441G>C p.L3147= | Silent (SNP) | VAF 49/63 reads (78%) | catalogued as COSV100197445, COSV54998927; called by muse, mutect2, varscan2
- FRMPD1 | c.2385C>A p.P795= | Silent (SNP) | VAF 104/271 reads (38%) | catalogued as rs760367564, COSV100899561; called by muse, mutect2, varscan2
- TBL3 | c.447C>G p.G149= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV100224904; called by muse, mutect2, varscan2
- DDX41 | c.*980G>A | 3'UTR (SNP) | VAF 47/98 reads (48%) | catalogued as rs1395944669, COSV100394357, COSV57254526; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21149T>A | Intron (SNP) | VAF 50/130 reads (38%) | catalogued as COSV99169585; called by muse, mutect2, varscan2
